Gene-level copy-number profile of tumor specimen TCGA-46-6026-01A from TCGA case TCGA-46-6026, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 81.8 years (29,890 days).
Specimen TCGA-46-6026-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.c250e95f-9a6a-4167-9406-994e3cb2bfef.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-46-6026-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/461e87fe-10a8-4be7-8637-c7006ca8a526

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 144; copy number 1: 9,275; copy number 2: 18,982; copy number 3: 6,720; copy number 4: 11,478; copy number 5: 9,725; copy number 6: 254; copy number 7: 1,729; copy number 8: 1,182; copy number 9: 115; copy number 10: 70; copy number 13: 68; copy number 15: 8; copy number 17: 32; copy number 61: 31; copy number 83: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-46-6026-01A-11D-1816-01): tumor purity 0.9, ploidy 3.7, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 144 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:172,380,028–172,380,487, 1 gene: AC108064.1.
- chr4:184,365,180–184,474,550, 3 genes (within-gene range 0–1): LINC02362, IRF2, SNORD79.
- chr9:21,994,139–22,128,103, 1 gene (within-gene range 0–1): CDKN2B-AS1.
- chr9:22,012,155–24,088,051, 20 genes: UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1.
- chr21:20,651,450–20,828,622, 2 genes (within-gene range 0–2): LINC00320, PPIAP1.
- chr21:23,281,736–24,547,942, 15 genes: RNU2-55P, D21S2088E, EEF1A1P1, TUBAP1, Y_RNA, AP000459.1, AP000961.1, AP000474.2, AP000474.1, AP000477.2, AP000477.3, AP000477.1, AP000470.1, LINC01689, LINC01684.
- chr21:25,880,550–26,171,128, 1 gene (within-gene range 0–2): APP.
- chr21:26,158,091–26,967,088, 13 genes: AP001439.1, AP000229.1, RNU6-926P, AP001595.2, AP001595.1, AP001596.1, CYYR1-AS1, AP001596.2, CYYR1, ADAMTS1, AP001599.1, ADAMTS5, MIR4759.
- chr21:27,358,885–30,829,759, 88 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13,220 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:91,356,755–123,992,178, 444 genes, copy number 5–7 (broad region; genes not listed).
- chr3:124,132,929–124,153,063, 2 genes, copy number 7: MIR5002, RPL7P15.
- chr3:134,597,801–135,260,467, 1 gene, copy number 7 (within-gene range 4–7): EPHB1.
- chr3:135,138,469–198,222,513, 1,089 genes, copy number 5–8 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 8–9 (broad region; genes not listed).
- chr6:167,607–170,738,536, 3,061 genes, copy number 5–83 (broad region; genes not listed).
- chr9:32,293,558–35,149,184, 133 genes, copy number 6 (broad region; genes not listed).
- chr11:167,784–825,573, 62 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr11:3,057,538–43,494,933, 792 genes, copy number 5 (broad region; genes not listed).
- chr11:45,355,371–54,603,998, 177 genes, copy number 5 (broad region; genes not listed).
- chr12:66,767–43,552,203, 927 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr12:44,244,394–60,419,293, 653 genes, copy number 5 (broad region; genes not listed).
- chr12:77,129,178–79,452,008, 15 genes, copy number 5 (within-gene range 2–5): AC079030.1, LINC02464, NAV3, AC073591.1, AC138331.1, AC073571.1, PRXL2AP1, LINC02424, AC128707.1, AC130415.1, AC079362.1, AC068993.1, AC068993.2, SYT1, AC090709.1.
- chr12:79,690,144–80,068,757, 9 genes, copy number 5 (within-gene range 2–5): AC073569.2, PPP1R12A, AC073569.3, AC073569.1, RNA5SP363, PPP1R12A-AS1, SNRPGP20, RPL7P38, RNU7-106P.
- chr12:80,935,736–81,261,210, 4 genes, copy number 5 (within-gene range 1–5): MIR618, ACSS3, AC078955.1, MIR4699.
- chr12:85,955,666–86,838,904, 1 gene, copy number 5 (within-gene range 1–5): MGAT4C.
- chr12:86,599,578–96,875,555, 175 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr15:97,215,812–101,933,350, 120 genes, copy number 6 (broad region; genes not listed).
- chr17:22,519,195–83,095,122, 2,138 genes, copy number 5–7 (broad region; genes not listed).
- chr19:94,062–2,051,244, 135 genes, copy number 7 (broad region; genes not listed).
- chr19:5,586,999–10,469,630, 260 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr19:11,420,604–22,716,991, 624 genes, copy number 7–13 (broad region; genes not listed).
- chr19:23,204,010–31,787,255, 120 genes, copy number 6–17 (broad region; genes not listed).
- chr19:37,779,686–38,852,347, 46 genes, copy number 10 (within-gene range 3–10): AC016582.2, AC016582.3, AC016582.1, WDR87, SIPA1L3, AC008395.1, AC011465.1, AC011479.3, AC011479.2, RN7SL663P, DPF1, SPINT2, PPP1R14A, AC011479.1, AC011479.4, Y_RNA, YIF1B, C19orf33, KCNK6, CATSPERG, AC005625.1, PSMD8, GGN, AC005789.1, SPRED3, FAM98C, RASGRP4, RYR1, AC067969.2, AC067969.1, MAP4K1, AC008649.1, EIF3K, ACTN4, AC008649.2, CAPN12, AC022144.1, LGALS7, LGALS7B, RNU6-140P, LGALS4, ECH1, AC008982.1, AC104534.1, HNRNPL, AC008982.2.
- chr19:40,717,112–41,706,976, 64 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,001. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
